Somatic mutation profile of tumor specimen TCGA-VR-A8ET-01A (aliquot TCGA-VR-A8ET-01A-11D-A403-09) from TCGA case TCGA-VR-A8ET, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.4 years (23,517 days).
Specimen TCGA-VR-A8ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4aafc32-ae33-4a1a-b0bf-59d3f3f31307.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8ET-10B (Blood Derived Normal), aliquot TCGA-VR-A8ET-10B-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80e02eb0-3109-4fa7-8362-8f3149482d49

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PROM2 | c.853C>G p.P285A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1244026973; called by muse, mutect2
- SLITRK1 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1210891744, COSV65674557; called by muse, mutect2, varscan2
- TTN | c.81340G>C p.D27114H (on ENST00000591111; = p.D19690H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | PolyPhen possibly damaging (0.789); catalogued as COSV59976258; called by muse, mutect2, varscan2
- BMPER | c.897A>C p.K299N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BSN | c.7030G>T p.G2344C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ECRG4 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAKMIP2 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MRPS36 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2
- MYO6 | c.553+1G>T p.X185_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- NOL4 | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CRYBG2 | c.1071C>T p.L357= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs749062561; called by muse, mutect2, varscan2
- MATK | c.966C>A p.A322= (on ENST00000310132 / NM_139355.3; = p.A323= on NM_002378.4) | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- NMUR2 | c.87C>T p.T29= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- PROM2 | c.852G>A p.E284= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- WDTC1 | c.184C>T p.L62= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV60090974; called by muse, mutect2
- C11orf40 | n.388C>A | RNA (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
